Somatic mutation profile of tumor specimen TCGA-WE-A8ZR-06A (aliquot TCGA-WE-A8ZR-06A-11D-A372-08) from TCGA case TCGA-WE-A8ZR, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 49.5 years (18,075 days).
Specimen TCGA-WE-A8ZR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1503a72a-9f86-40d4-b521-a0f93e48735e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8ZR-10A (Blood Derived Normal), aliquot TCGA-WE-A8ZR-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20452885-2127-46d1-9827-ce48ca840e43

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAM11 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749481116, COSV52345556; called by muse, mutect2, varscan2
- ADAMTS5 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.138); catalogued as COSV53175172; called by muse, mutect2, varscan2
- APOBR | c.2359G>A p.E787K (on ENST00000431282; = p.E796K on NM_018690.4) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as rs1468297033, COSV60494004; called by muse, mutect2, varscan2
- BECN1 | c.10T>A p.S4T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV100831112; called by muse, mutect2, varscan2
- CNTNAP5 | c.2317G>T p.E773* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV101443468; called by muse, mutect2, varscan2
- COL27A1 | c.2727+1G>T p.X909_splice | Splice Site (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100620958; called by muse, mutect2, varscan2
- CYP2A6 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV56533766; called by muse, mutect2, varscan2
- FER1L6 | c.3847G>A p.D1283N | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV101205779; called by muse, mutect2, varscan2
- FGD2 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs377492771, COSV51463112; called by mutect2, varscan2
- FGD6 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs1045074245, COSV59691619; called by muse, mutect2
- GPHN | c.790A>T p.S264C (on ENST00000315266 / NM_001377519.1; = p.S297C on NM_020806.5) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100016073; called by muse, mutect2, varscan2
- HSPBAP1 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs1164389169, COSV100063368; called by muse, mutect2, varscan2
- MLEC | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV99949632; called by muse, varscan2
- MLEC | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.041); catalogued as rs1372154944, COSV99949634; called by muse, varscan2
- NFATC4 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs955445198, COSV51596369; called by mutect2, varscan2
- NRXN1 | c.1616A>G p.D539G | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100454716; called by muse, mutect2, varscan2
- PIWIL1 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99806327; called by muse, mutect2, varscan2
- PRKD3 | c.1019T>A p.I340K | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99306053; called by muse, mutect2, varscan2
- SCCPDH | c.1104G>T p.E368D | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV100829724; called by muse, mutect2, varscan2
- SDCCAG8 | c.1873A>T p.S625C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV100654172; called by muse, mutect2, varscan2
- SLC16A8 | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.495); catalogued as COSV100260078; called by muse, mutect2
- TGOLN2 | c.483A>T p.Q161H | Missense Mutation (SNP) | VAF 284/734 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV99965035; called by muse, mutect2, varscan2
- CHRNA4 | c.1842G>A p.T614= | Silent (SNP) | VAF 59/86 reads (69%) | catalogued as rs727503871, COSV100937405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECD | c.1389A>G p.K463= | Silent (SNP) | VAF 49/58 reads (84%) | catalogued as COSV100881414; called by muse, mutect2, varscan2
- PCTP | c.552G>T p.P184= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as rs371579881, COSV52123005, COSV99273768; called by muse, mutect2, varscan2
- UNC79 | c.4614C>T p.I1538= (on ENST00000393151 / NM_001346218.2; = p.I1361= on NM_020818.5) | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs1391980240, COSV56381742, COSV99830257; called by muse, mutect2, varscan2
- ZFHX4 | c.4050G>A p.P1350= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs749725605, COSV50737398, COSV99266767; called by muse, mutect2, varscan2
